Somatic mutation profile of tumor specimen MMRF_1986_1_BM_CD138pos (aliquot MMRF_1986_1_BM_CD138pos_T1_KHS5U_L08065) from MMRF case MMRF_1986, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.5 years (25,372 days).
Specimen MMRF_1986_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7ff6bfb-c9b1-4238-bcd2-2e331bcb4082.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1986_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1986_1_PB_CD3pos_C2_KHS5U_L08066; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3ba7ce1-26c4-472f-8989-393378f2a96a

The open-access MAF lists 1,387 somatic variants for this specimen: 454 protein-altering or splice-affecting, 187 silent, 746 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 396, 3'UTR 378, Intron 187, Silent 187, 5'UTR 95, Nonsense Mutation 39, 3'Flank 35, 5'Flank 28, RNA 23, Splice Site 7, Splice Region 6, Frame Shift Del 4.

Variants (750 of 1,387; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1901A>G p.D634G (on ENST00000288602 / NM_001374244.1; = p.D594G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs121913338, COSV56065695, COSV56224199, COSV56283955; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AAAS | c.1109G>A p.G370E | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV52933802; called by muse, mutect2, varscan2
- ABCB11 | c.524G>A p.R175K | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99028329; called by muse, mutect2, varscan2
- ABCC5 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.546); catalogued as rs770885431; called by muse, mutect2, varscan2
- ABHD15 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs924408839; called by muse, mutect2, varscan2
- ACAN | c.630-1G>A p.X210_splice | Splice Site (SNP) | VAF 8/248 reads (3%) | catalogued as COSV61359964; called by muse, mutect2
- ACE | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.247); catalogued as rs369022610; called by muse, mutect2
- ADAD1 | c.1274G>A p.R425K | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.454); catalogued as COSV56641632, COSV99634960; called by muse, mutect2
- ADGRA1 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.75); PolyPhen benign (0.138); catalogued as COSV66927508; called by muse, mutect2, varscan2
- AFAP1 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 10/271 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.115); catalogued as COSV61794753; called by muse, mutect2
- AGTPBP1 | c.2264G>A p.G755E (on ENST00000357081 / NM_001330701.2; = p.G715E on NM_015239.2) | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV61275326; called by muse, mutect2, varscan2
- ANAPC5 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 6/114 reads (5%) | catalogued as COSV55843008; called by muse, mutect2
- ANO4 | c.1639C>T p.Q547* (on ENST00000392977 / NM_001286615.2; = p.Q512* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV54590877; called by muse, mutect2, varscan2
- ANO5 | c.2420G>A p.R807K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as COSV61084006; called by muse, mutect2
- ARID3B | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.968); catalogued as COSV100654487, COSV60558409; called by muse, mutect2, varscan2
- ASPH | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as COSV65243453; called by muse, mutect2, varscan2
- BACE2 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs1377506643, COSV57737272; called by muse, mutect2
- BCAS4 | c.112C>G p.Q38E | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs924128505; called by muse, mutect2
- BEST3 | c.1963G>C p.D655H | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV58301472; called by muse, mutect2
- C17orf49 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.169); catalogued as COSV52348976; called by mutect2, varscan2
- C9orf131 | c.1497G>C p.E499D | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.482); catalogued as rs758910528, COSV56613180; called by muse, mutect2, varscan2
- CACNA1D | c.5930C>T p.S1977L (on ENST00000350061 / NM_001128840.3; = p.S1997L on NM_000720.4) | Missense Mutation (SNP) | VAF 82/563 reads (15%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.009); catalogued as rs202077075, COSV55441250; called by muse, mutect2, varscan2
- CARD11 | c.1251G>T p.M417I | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV101211092; called by muse, mutect2, varscan2
- CASKIN1 | c.3319G>A p.E1107K | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.709); catalogued as rs558666059; called by muse, varscan2
- CCDC24 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs991649216; called by muse, mutect2, varscan2
- CDK12 | c.733G>T p.D245Y | Missense Mutation (SNP) | VAF 75/142 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV101420494, COSV71000082; called by muse, mutect2, varscan2
- CELF1 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 15/229 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV60114224; called by muse, mutect2
- CEP131 | c.2969C>T p.S990F (on ENST00000269392 / NM_001319228.2; = p.S987F on NM_014984.4) | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.358); catalogued as COSV53952871; called by muse, mutect2, varscan2
- CFAP61 | c.1513G>C p.D505H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV55648125; called by muse, mutect2, varscan2
- CIART | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.437); catalogued as rs1356704654; called by muse, mutect2, varscan2
- CMKLR1 | c.288C>G p.I96M (on ENST00000312143 / NM_001142344.2; = p.I94M on NM_004072.3) | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56436766; called by muse, mutect2
- CNOT11 | c.206C>G p.S69W | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as rs373337293; called by muse, mutect2, varscan2
- COL4A2 | c.4229G>A p.R1410Q | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.19); catalogued as rs1004346642, COSV64629756; called by muse, mutect2, varscan2
- CPN2 | c.1009G>T p.E337* | Nonsense Mutation (SNP) | VAF 57/173 reads (33%) | catalogued as COSV60471211; called by muse, mutect2, varscan2
- CREB3L3 | c.379C>A p.H127N | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.142); catalogued as COSV50172203; called by muse, mutect2
- CRISP2 | c.194G>A p.R65K | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs138105311, COSV59257360; called by muse, mutect2, varscan2
- CYP2F1 | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs748451971; called by muse, mutect2, varscan2
- CYP3A4 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV60501377; called by muse, mutect2, varscan2
- CYTH3 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs1306610408; called by muse, mutect2, varscan2
- DACH1 | c.1837G>C p.D613H (on ENST00000619232 / NM_001366712.1; = p.D359H on NM_004392.6) | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV57520718; called by muse, mutect2
- DCAF1 | c.764C>G p.S255* | Nonsense Mutation (SNP) | VAF 110/393 reads (28%) | catalogued as COSV60047203; called by muse, mutect2, varscan2
- DCAF12 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1298404287, COSV63511636, COSV63513121; called by muse, mutect2
- DGAT2 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.085); catalogued as rs879238086; called by muse, mutect2, varscan2
- DGKE | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.07); catalogued as rs915029037; called by muse, mutect2, varscan2
- DGKI | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.637); catalogued as rs1356117537; called by muse, mutect2
- DNAH5 | c.6086G>A p.G2029D | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD148006; called by muse, mutect2, varscan2
- DOCK1 | c.4297G>A p.E1433K | Missense Mutation (SNP) | VAF 74/156 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs777958830, COSV54732049; called by muse, mutect2, varscan2
- DST | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1199173298, COSV100418849; called by muse, mutect2, varscan2
- DYNC2H1 | c.12512C>T p.S4171L | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV62106794; called by muse, mutect2
- ELN | c.2045G>A p.G682E (on ENST00000320399 / NM_001278939.1; = p.G649E on NM_000501.4) | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.375); catalogued as rs200041224, CD991691; called by muse, mutect2, varscan2
- EOMES | c.1274C>T p.S425L | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as COSV99842394; called by muse, mutect2
- EOMES | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV55413140; called by muse, mutect2
- ERCC6 | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs886047035; ClinVar: uncertain significance; called by muse, varscan2
- FARP2 | c.2599C>T p.R867C | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs547134701; called by muse, mutect2, varscan2
- FIGNL1 | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 9/213 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63553520; called by muse, mutect2
- FSTL1 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762080512; called by muse, mutect2, varscan2
- FUBP1 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 27/56 reads (48%) | catalogued as COSV53936319; called by muse, mutect2, varscan2
- FUT7 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs371156257; called by muse, mutect2, varscan2
- FYCO1 | c.3097G>C p.E1033Q | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.197); catalogued as COSV56119896; called by muse, mutect2, varscan2
- GAB2 | c.1400G>C p.R467P (on ENST00000361507 / NM_080491.3; = p.R429P on NM_012296.3) | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.503); catalogued as rs138155762; called by muse, mutect2, varscan2
- GAS2L1 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as rs746357740; called by muse, mutect2, varscan2
- GNG13 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 54/89 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs773688604, COSV50210320; called by muse, mutect2, varscan2
- GON4L | c.2422G>C p.E808Q | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV55191715; called by muse, mutect2, varscan2
- GPR107 | c.1649C>T p.S550L (on ENST00000372406 / NM_001136557.2; = p.S502L on NM_020960.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1347097040, COSV100714672; called by muse, mutect2, varscan2
- GRIK1 | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 58/303 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58710747; called by muse, mutect2, varscan2
- GUCY1A2 | c.1271C>G p.S424C | Missense Mutation (SNP) | VAF 8/137 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56479956; called by muse, mutect2
- H1-7 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT tolerated (0.17); PolyPhen benign (0.084); catalogued as COSV58602394; called by muse, mutect2, varscan2
- HOXC13 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.953); catalogued as rs1020710166; called by muse, mutect2, varscan2
- HS3ST3B1 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 58/96 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.228); catalogued as rs143010519; called by muse, mutect2, varscan2
- IGDCC4 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV61535278; called by muse, mutect2
- IKZF3 | c.639G>C p.Q213H | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53104881; called by muse, mutect2, varscan2
- ITPRID1 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.273); catalogued as COSV60082327; called by muse, mutect2
- KANK3 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV58362762; called by muse, mutect2, varscan2
- KDM1A | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.32); catalogued as rs996794739; called by muse, mutect2
- KIAA2012 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (0.19); catalogued as rs889091379; called by muse, mutect2
- KIF15 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV58159914; called by muse, mutect2, varscan2
- KLHL32 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV100987214, COSV65112752; called by muse, mutect2, varscan2
- KRBA1 | c.2792C>T p.S931F | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs777312910; called by muse, mutect2, varscan2
- LEPR | c.2366C>A p.S789Y | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as rs771996587; called by muse, varscan2
- LGALS3 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 24/44 reads (55%) | catalogued as COSV99582276; called by muse, mutect2, varscan2
- LMF1 | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs759097865; called by muse, mutect2, varscan2
- LRRC25 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 84/252 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.761); catalogued as rs1189698972; called by muse, mutect2, varscan2
- MAP3K11 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as rs1380845904, COSV100482263, COSV100482362; called by muse, mutect2
- MAPK10 | c.1481C>T p.S494F | Missense Mutation (SNP) | VAF 6/95 reads (6%) | PolyPhen possibly damaging (0.692); catalogued as rs1031398385; called by muse, mutect2
- MAPK9 | c.1123C>T p.Q375* | Nonsense Mutation (SNP) | VAF 7/119 reads (6%) | catalogued as COSV58121407; called by muse, mutect2
- MARCO | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV59054969; called by muse, mutect2, varscan2
- MASTL | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1379798710; called by muse, mutect2
- MDH1 | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51864887; called by muse, mutect2, varscan2
- MDM4 | c.517G>C p.D173H | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV65794983; called by muse, mutect2, varscan2
- MRPS30 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.028); catalogued as rs1017075752; called by muse, mutect2
- MYOM1 | c.3799G>A p.E1267K | Missense Mutation (SNP) | VAF 78/174 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs1337183974; called by muse, mutect2, varscan2
- NAV3 | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV57082953; called by muse, mutect2, varscan2
- NAXD | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs1290618678; called by mutect2, varscan2
- NFKB2 | c.2423G>A p.R808Q | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs1261067166; called by muse, varscan2
- NR1D1 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.04); catalogued as rs143622936; called by muse, mutect2, varscan2
- NUP85 | c.1194G>C p.M398I | Missense Mutation (SNP) | VAF 5/115 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV99823156; called by muse, mutect2
- OR52N1 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as rs548980477, COSV57693572; called by muse, mutect2, varscan2
- OSBP | c.1728G>C p.K576N | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV55662322, COSV55665159; called by muse, mutect2
- P2RX2 | c.1403C>G p.S468C (on ENST00000343948 / NM_170683.4; = p.S370C on NM_012226.5) | Missense Mutation (SNP) | VAF 86/171 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV57691023; called by muse, mutect2, varscan2
- PARPBP | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated (0.61); PolyPhen benign (0.297); catalogued as rs776726899, COSV59673157; called by muse, mutect2, varscan2
- PCDH9 | c.2845C>T p.H949Y | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100119003; called by muse, mutect2, varscan2
- PCOLCE2 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as rs139818603, COSV55997971; called by muse, mutect2, varscan2
- PCSK2 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV52737497; called by muse, mutect2, varscan2
- PFKFB4 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 32/94 reads (34%) | PolyPhen probably damaging (0.937); catalogued as rs1560177249, COSV51680968; called by muse, mutect2, varscan2
- PKHD1L1 | c.5635G>A p.E1879K | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.232); catalogued as COSV65749542; called by muse, mutect2
- PLD4 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.076); catalogued as rs1397226584; called by muse, mutect2, varscan2
- POGLUT1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV55156991; called by muse, mutect2, varscan2
- PPP1R3D | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV100674649; called by muse, mutect2, varscan2
- PPP2R1A | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs1247831715, COSV59046721; called by muse, mutect2, varscan2
- PPP6R3 | c.2296G>A p.E766K (on ENST00000393800 / NM_001352375.2; = p.E686K on NM_018312.5) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.88); PolyPhen benign (0.15); catalogued as COSV99676707; called by muse, mutect2, varscan2
- PRDM1 | c.2185G>T p.E729* | Nonsense Mutation (SNP) | VAF 23/304 reads (8%) | catalogued as COSV64847342; called by muse, mutect2
- PRDM16 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 89/149 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.265); catalogued as rs369539275; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRPF38B | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs1158752325, COSV100898349; called by muse, mutect2
- PRRC2C | c.1966C>G p.Q656E (on ENST00000367742; = p.Q654E on NM_015172.4) | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as rs760248556, COSV58910994; called by muse, mutect2, varscan2
- PRSS57 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 32/65 reads (49%) | catalogued as COSV61385534; called by muse, mutect2, varscan2
- PWWP3A | c.869C>T p.S290L (on ENST00000627377; = p.S289L on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1298281521, COSV60903447; called by muse, mutect2
- PXDNL | c.2881del p.A961Pfs*28 | Frame Shift Del (DEL) | VAF 44/110 reads (40%) | catalogued as COSV100680846, COSV100683167; called by mutect2, pindel, varscan2
- QRFPR | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.56); catalogued as rs772009418, COSV57680028; called by muse, mutect2, varscan2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, varscan2
- RIOX2 | c.1357G>T p.V453L (on ENST00000333396 / NM_001042533.2; = p.V452L on NM_032778.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/509 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV51712009; called by muse, mutect2, varscan2
- RNF111 | c.2785G>C p.D929H (on ENST00000557998 / NM_001270530.1; = p.D921H on NM_017610.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100789112; called by muse, mutect2, varscan2
- ROBO1 | c.2060C>T p.S687F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71391988; called by muse, mutect2, varscan2
- RYR1 | c.7243C>T p.R2415W | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.852); catalogued as rs368013861; called by muse, varscan2
- SDCCAG8 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs368258515; called by muse, mutect2, varscan2
- SEC24C | c.1691C>T p.S564L | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs891774217, COSV59540435; called by muse, mutect2, varscan2
- SETD6 | c.441G>A p.W147* (on ENST00000219315 / NM_001160305.4; = p.W123* on NM_024860.3) | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as rs1485826231; called by muse, varscan2
- SETDB1 | c.3759-3C>G | Splice Region (SNP) | VAF 16/242 reads (7%) | catalogued as COSV99644642; called by muse, mutect2
- SGO2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs575775244; called by muse, mutect2, varscan2
- SH2D1B | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV63391979; called by muse, mutect2
- SLC11A1 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1407747739, COSV51919209; called by muse, mutect2, varscan2
- SLC24A4 | c.1643G>A p.G548E | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV54110277; called by muse, mutect2, varscan2
- SLC34A2 | c.254G>C p.R85T | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs533106793; called by muse, mutect2, varscan2
- SLC44A5 | c.244A>C p.K82Q | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.058); catalogued as rs1430999019; called by muse, mutect2, varscan2
- SLIT2 | c.4376G>C p.R1459T | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1322158842; called by muse, mutect2, varscan2
- SPRTN | c.1097C>G p.S366C | Missense Mutation (SNP) | VAF 14/365 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as rs961832850; called by muse, mutect2
- SPTBN5 | c.10177G>C p.E3393Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as rs1454314471; called by mutect2, varscan2
- SSBP3 | c.1001C>T p.S334L (on ENST00000371320 / NM_145716.4; = p.S314L on NM_018070.5) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.405); catalogued as COSV100486349; called by muse, mutect2
- SSX2IP | c.899G>C p.R300T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV60552271; called by muse, mutect2
- SUMF1 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 89/297 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.379); catalogued as rs1218513120; called by muse, mutect2, varscan2
- SYTL2 | c.1699C>G p.L567V (on ENST00000528231 / NM_001162951.2; = p.L583V on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as rs1461495861; called by muse, mutect2
- TACC1 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | catalogued as COSV52528934; called by muse, mutect2
- TBC1D25 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 82/85 reads (96%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV100952147; called by muse, mutect2, varscan2
- TBPL2 | c.779G>C p.G260A | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55971836, COSV55972219; called by muse, mutect2, varscan2
- TBR1 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 74/127 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as rs1413114353, COSV67418288; called by muse, mutect2, varscan2
- TERT | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs377016753; called by muse, mutect2, varscan2
- TIMM8B | c.22G>T p.D8Y | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV99736038; called by muse, mutect2
- TOP1MT | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs763485070; called by muse, mutect2, varscan2
- TP53INP1 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 142/287 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs773733025; called by muse, mutect2, varscan2
- TRAV16 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as rs779843515; called by muse, mutect2, varscan2
- TRAV8-1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.162); catalogued as rs1240240426; called by muse, mutect2, varscan2
- TRMT61B | c.298C>G p.R100G | Missense Mutation (SNP) | VAF 81/165 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs550076940, COSV60258731; called by muse, mutect2, varscan2
- TTC30B | c.741G>C p.Q247H | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs1337063965; called by muse, mutect2
- TTN | c.13575G>C p.R4525S (on ENST00000591111; = p.R3598S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/156 reads (45%) | PolyPhen benign (0.022); catalogued as COSV100606623; called by muse, varscan2
- UNC80 | c.6061G>A p.E2021K | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.987); catalogued as COSV55891148; called by muse, mutect2
- VGF | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.746); catalogued as rs35400704, COSV50801779, COSV99972772, COSV99973099; called by muse, mutect2, varscan2
- WDR72 | c.2866C>T p.R956* | Nonsense Mutation (SNP) | VAF 27/47 reads (57%) | catalogued as rs751269504, COSV64743965; called by muse, mutect2, varscan2
- WNK2 | c.5817G>C p.E1939D (on ENST00000297954 / NM_001282394.1; = p.E1902D on NM_006648.3) | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV52950653; called by muse, varscan2
- ZFYVE9 | c.3732G>T p.E1244D | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as COSV55094621; called by muse, mutect2, varscan2
- ZNF10 | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV50216303; called by muse, mutect2
- ZNF135 | c.1651G>A p.E551K (on ENST00000313434 / NM_001289401.2; = p.E563K on NM_003436.4) | Missense Mutation (SNP) | VAF 29/261 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.326); catalogued as COSV57883558; called by muse, mutect2, varscan2
- ZNF180 | c.1627C>T p.H543Y | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55421921; called by muse, mutect2, varscan2
- ZNF480 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 15/354 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1246348105; called by muse, mutect2
- ZNF777 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.12); catalogued as rs751346353; called by muse, mutect2, varscan2
- ZNF883 | c.1135G>C p.E379Q | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.021); catalogued as COSV71309068; called by muse, mutect2, varscan2
- AASDH | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ABI3BP | c.2008G>A p.G670R | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ACOX1 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADAM29 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.92); PolyPhen benign (0.033); called by muse, mutect2
- AFG1L | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.315); called by muse, mutect2
- AFG3L2 | c.2146C>G p.L716V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.536); called by mutect2, varscan2
- AFG3L2 | c.296C>G p.S99* | Nonsense Mutation (SNP) | VAF 24/205 reads (12%) | called by muse, mutect2, varscan2
- AHNAK2 | c.697C>G p.L233V | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- AMOTL2 | c.2171G>A p.R724K (on ENST00000422605; = p.R725K on NM_016201.4) | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.1729G>C p.D577H | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ANKAR | c.3787C>T p.H1263Y | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- ANKIB1 | c.2842G>C p.D948H | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- ANKRD26 | c.3229G>C p.E1077Q | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKS1B | c.2935C>G p.Q979E | Missense Mutation (SNP) | VAF 13/257 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.622); called by muse, mutect2
- ANTKMT | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AOX1 | c.683A>G p.K228R | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.035); called by muse, mutect2
- ARHGAP28 | c.374T>A p.L125Q | Missense Mutation (SNP) | VAF 158/277 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP35 | c.3166C>G p.L1056V | Missense Mutation (SNP) | VAF 95/293 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- ASAP1 | c.2155G>A p.D719N | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ASH1L | c.3464C>G p.S1155* | Nonsense Mutation (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- ASZ1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- ATAD2 | c.2259T>A p.D753E | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP2B1 | c.3424C>T p.H1142Y | Missense Mutation (SNP) | VAF 71/144 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- ATP2C1 | c.2153C>G p.S718* | Nonsense Mutation (SNP) | VAF 25/109 reads (23%) | called by muse, mutect2, varscan2
- ATRIP | c.266G>C p.R89T | Missense Mutation (SNP) | VAF 146/447 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- BBS7 | c.1788G>C p.E596D | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BCL2 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); called by muse, mutect2
- BIRC6 | c.4010G>A p.R1337K | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BMP2K | c.1573C>T p.Q525* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- BRWD3 | c.5153G>A p.R1718K | Missense Mutation (SNP) | VAF 39/39 reads (100%) | SIFT tolerated, low confidence (0.6); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- BTBD8 | c.1591G>A p.D531N (on ENST00000636805 / NM_001376131.1; = p.D18N on NM_015237.4) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- C1orf100 | c.326-1G>A p.X109_splice | Splice Site (SNP) | VAF 14/174 reads (8%) | called by muse, mutect2
- C1orf87 | c.830G>T p.R277I | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, varscan2
- CAND1 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- CAND2 | c.539T>G p.L180R (on ENST00000456430 / NM_001162499.2; = p.L87R on NM_012298.3) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CARD19 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 69/229 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CASKIN2 | c.901C>G p.L301V | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CASP10 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CATSPER3 | c.267C>G p.F89L | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC168 | c.19442C>G p.S6481* | Nonsense Mutation (SNP) | VAF 11/145 reads (8%) | called by muse, mutect2
- CCDC174 | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 10/284 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.058); called by muse, mutect2
- CCDC7 | c.2606C>A p.S869* | Nonsense Mutation (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
- CCNP | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CCT3 | c.1266G>C p.L422F | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CENPBD1 | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2
- CKAP5 | c.1509G>C p.K503N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- CLEC4F | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- CMTM4 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2
- CNR1 | c.16G>C p.D6H | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL19A1 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2
- CPT1A | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CROT | c.117G>A p.V39= | Splice Region (SNP) | VAF 47/153 reads (31%) | called by muse, mutect2, varscan2
- CTDP1 | c.1022G>A p.R341K | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CTRL | c.281C>G p.S94* | Nonsense Mutation (SNP) | VAF 19/97 reads (20%) | called by muse, mutect2, varscan2
- CUBN | c.10220_10234del p.R3407_P3412delinsT | In Frame Del (DEL) | VAF 24/57 reads (42%) | called by mutect2, pindel, varscan2
- CUX1 | c.92G>T p.R31I (on ENST00000292535 / NM_181552.4; = p.R42I on NM_001913.5) | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DAZAP1 | c.1063G>C p.D355H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- DDX51 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DHX15 | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 110/250 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- DHX36 | c.1372A>G p.T458A | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DHX40 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHX9 | c.2965G>A p.D989N | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- DNAAF6 | c.516G>T p.K172N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.322); called by muse, mutect2
- DNAH1 | c.6499G>A p.E2167K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- DNAI3 | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); called by muse, mutect2
- DOCK7 | c.4055C>T p.S1352L (on ENST00000635253 / NM_001367561.1; = p.S1321L on NM_033407.3) | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, varscan2
- DOCK7 | c.3781_3781+3del p.X1261_splice (on ENST00000635253 / NM_001367561.1; = p.X1230_splice on NM_033407.3) | Splice Site (DEL) | VAF 11/24 reads (46%) | called by mutect2, pindel, varscan2
- DUOX1 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); called by muse, mutect2
- E2F7 | c.116C>G p.S39* | Nonsense Mutation (SNP) | VAF 30/49 reads (61%) | called by muse, mutect2, varscan2
- ECEL1 | c.2218G>T p.E740* | Nonsense Mutation (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- EFCAB14 | c.705G>C p.L235F | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.588); called by muse, mutect2
- ENPP5 | c.1414C>G p.Q472E | Missense Mutation (SNP) | VAF 98/221 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- EPHX1 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.367); called by muse, mutect2
- ERVMER34-1 | c.660G>C p.L220F | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.08); called by muse, varscan2
- EVPL | c.4042G>A p.E1348K | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- EXPH5 | c.2186C>G p.P729R | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- F5 | c.6512C>A p.S2171Y | Missense Mutation (SNP) | VAF 19/280 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2
- F7 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- FAM71F1 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FASTKD3 | c.247C>G p.Q83E | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.038); called by muse, mutect2
- FBXL5 | c.1817C>T p.S606F | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- FBXO3 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 13/290 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.899); called by muse, mutect2
- FBXO9 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 216/449 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FCGBP | c.6548C>T p.S2183L | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- FGD6 | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.543); called by muse, mutect2
- FOXA3 | c.468G>C p.E156D | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); called by muse, mutect2
- FOXB2 | c.574C>G p.P192A | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.037); called by muse, varscan2
- FSCB | c.149G>C p.R50T | Missense Mutation (SNP) | VAF 69/149 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- FTSJ3 | c.1291-3C>T | Splice Region (SNP) | VAF 54/101 reads (53%) | called by muse, mutect2, varscan2
- GDE1 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GDF10 | c.1147G>T p.V383L | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GET3 | c.456G>C p.M152I | Missense Mutation (SNP) | VAF 84/254 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.034); called by muse, varscan2
- GJC1 | c.1087C>T p.H363Y | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- GNAT1 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2
- GOLGA6L2 | c.330G>C p.Q110H | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- GOLGB1 | c.1999G>T p.D667Y | Missense Mutation (SNP) | VAF 8/236 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2
- GTF3C1 | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GUCY2C | c.2556C>G p.I852M | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- HABP2 | c.683A>C p.Y228S | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- HEATR5A | c.5134G>A p.G1712R | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- HECW1 | c.4231G>A p.E1411K | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- HGS | c.1730G>A p.G577E | Missense Mutation (SNP) | VAF 73/132 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- HLA-DOA | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- HMGCS1 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- HNRNPH2 | c.945G>C p.M315I | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HNRNPUL2 | c.752-8C>G | Splice Region (SNP) | VAF 35/65 reads (54%) | called by muse, mutect2, varscan2
- HORMAD1 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- HPS5 | c.1384C>T p.Q462* (on ENST00000349215 / NM_181507.2; = p.Q348* on NM_007216.4) | Nonsense Mutation (SNP) | VAF 32/61 reads (52%) | called by muse, mutect2, varscan2
- HYAL4 | c.287G>C p.G96A | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- IFNK | c.458G>A p.R153K | Missense Mutation (SNP) | VAF 10/215 reads (5%) | SIFT tolerated (0.96); PolyPhen benign (0.022); called by muse, mutect2
- ILDR1 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IPMK | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- IRX4 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.058); called by mutect2, varscan2
- ITPR1 | c.3538-1G>C p.X1180_splice (on ENST00000354582; = p.X1165_splice on NM_002222.7) | Splice Site (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- ITSN2 | c.1555C>G p.Q519E | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- KAT2A | c.2013G>C p.Q671H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNJ8 | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- KCNK4 | c.694C>G p.Q232E | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- KCNQ4 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- KDM3B | c.1350G>C p.Q450H | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.275); called by muse, mutect2
- KIAA1217 | c.3851C>G p.S1284C | Missense Mutation (SNP) | VAF 67/132 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- KIAA1549 | c.4241C>T p.S1414L | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIF4A | c.1735G>A p.V579I | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIZ | c.1307C>G p.S436C | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KLF9 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- KPNA7 | c.772C>G p.L258V | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- KRCC1 | c.259C>A p.Q87K | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.215); called by muse, mutect2
- KRT39 | c.907C>G p.Q303E | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- KRTAP16-1 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- LDLR | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- LMNB2 | c.1159G>C p.E387Q | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LPIN1 | c.2510C>G p.S837C | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, varscan2
- LRRC41 | c.2021-1G>C p.X674_splice | Splice Site (SNP) | VAF 49/104 reads (47%) | called by muse, varscan2
- LTF | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LYRM4 | c.110G>C p.R37T | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- MACF1 | c.3317C>T p.S1106L | Missense Mutation (SNP) | VAF 73/128 reads (57%) | called by muse, mutect2, varscan2
- MAP3K6 | c.2813C>G p.S938* | Nonsense Mutation (SNP) | VAF 40/76 reads (53%) | called by muse, mutect2, varscan2
- MARF1 | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 9/104 reads (9%) | called by muse, mutect2
- MEAK7 | c.122C>A p.S41* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | called by mutect2, varscan2
- MEGF6 | c.3346C>G p.Q1116E | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MEPE | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2
- MFAP3L | c.540G>C p.K180N | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- MIS18BP1 | c.2992C>T p.Q998* | Nonsense Mutation (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2, varscan2
- MMP27 | c.488G>C p.R163P | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MORF4L2 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MOV10 | c.1962G>C p.E654D | Missense Mutation (SNP) | VAF 73/144 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MRPL45 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- MSANTD3 | c.231C>G p.I77M | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.402); called by muse, varscan2
- MST1R | c.3676G>A p.D1226N | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- MTA1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MUC1 | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- MUC4 | c.695C>T p.T232I | Missense Mutation (SNP) | VAF 7/163 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2
- MUC4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/74 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MX2 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 90/354 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYBPC3 | c.2731G>A p.E911K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); called by muse, varscan2
- MYO3B | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- NAP1L2 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 54/55 reads (98%) | SIFT tolerated (0.17); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- NCDN | c.2062C>G p.Q688E | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.482); called by muse, mutect2
- NCOA7 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NDUFS2 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- NEB | c.1966C>G p.Q656E | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.953); called by muse, mutect2
- NFIA | c.499C>G p.H167D | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NFKB2 | c.1456G>T p.E486* | Nonsense Mutation (SNP) | VAF 18/28 reads (64%) | called by muse, varscan2
- NFKB2 | c.2347G>C p.D783H | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); called by muse, varscan2
- NID2 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NMU | c.277C>G p.Q93E | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- NRG3 | c.1441C>A p.Q481K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- NRXN1 | c.2906G>A p.G969E | Missense Mutation (SNP) | VAF 76/144 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- NSUN6 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.347); called by muse, mutect2
- NT5C1A | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NUCB2 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, mutect2
- NUP160 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 24/471 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); called by muse, mutect2
- NUP205 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- NUP43 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- OBSCN | c.21026C>A p.S7009Y | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR11G2 | c.421_443del p.F141Rfs*11 | Frame Shift Del (DEL) | VAF 10/126 reads (8%) | called by mutect2, pindel
- OR2D2 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR52K1 | c.817C>G p.R273G | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2
- OR5W2 | c.855G>C p.L285F | Missense Mutation (SNP) | VAF 86/182 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- OR6C3 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 66/114 reads (58%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- OR9A2 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 15/438 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2
- OTUD7B | c.1589C>T p.S530L | Missense Mutation (SNP) | VAF 30/369 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- PAN2 | c.2374C>T p.P792S (on ENST00000425394 / NM_001127460.3; = p.P788S on NM_014871.5) | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PAXIP1 | c.2851G>A p.E951K | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- PCGF6 | c.1034C>G p.S345C (on ENST00000369847 / NM_001011663.2; = p.S270C on NM_032154.4) | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PCNA | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PCP2 | c.398C>A p.T133K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- PDE2A | c.1725G>A p.M575I | Missense Mutation (SNP) | VAF 73/126 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- PDHA2 | c.355C>T p.H119Y | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDILT | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 5/114 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- PGS1 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.062); called by muse, mutect2
- PHACTR4 | c.1874G>A p.R625K (on ENST00000373839 / NM_001350159.2; = p.R635K on NM_023923.4) | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PHC3 | c.1184C>G p.S395C (on ENST00000494943 / NM_001308116.2; = p.S407C on NM_024947.4) | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- PHIP | c.4346C>G p.S1449C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PHKA2 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 78/78 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- PLAAT3 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2
- PLAGL1 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- PLCG2 | c.1769C>G p.S590C | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLXNB2 | c.364C>G p.L122V | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.199); called by muse, mutect2
- POLE | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- PPME1 | c.272C>G p.S91C | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRH1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PRLR | c.1459G>C p.D487H | Missense Mutation (SNP) | VAF 66/115 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- PROM2 | c.1259G>A p.R420K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PROM2 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.434); called by muse, mutect2
- PRR22 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- PTCHD3 | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); called by muse, mutect2
- PTGR2 | c.506C>G p.S169C | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRG | c.2376-8C>T | Splice Region (SNP) | VAF 35/115 reads (30%) | called by muse, mutect2, varscan2
- PURB | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.43); called by muse, mutect2
- RAB3GAP1 | c.961C>T p.Q321* | Nonsense Mutation (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- RCOR1 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- REC114 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RERE | c.2690C>A p.S897Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2
- RNF103 | c.1225G>C p.D409H | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ROBO1 | c.4472del p.K1491Sfs*16 | Frame Shift Del (DEL) | VAF 42/146 reads (29%) | called by mutect2, varscan2
- ROMO1 | c.129C>T p.L43= | Splice Region (SNP) | VAF 69/153 reads (45%) | called by muse, mutect2, varscan2
- RSBN1L | c.404T>G p.L135R | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- SAMD9 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SAMSN1 | c.231G>A p.M77I | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2
- SARM1 | c.1360G>T p.D454Y | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SATB1 | c.1690G>A p.D564N | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCLT1 | c.1876C>G p.Q626E | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- SEMA3C | c.429C>G p.N143K | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); called by muse, mutect2
- SERPINB2 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- SIM2 | c.458-1G>A p.X153_splice | Splice Site (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2, varscan2
- SLC16A11 | c.382C>G p.L128V (on ENST00000308009; = p.L104V on NM_153357.3) | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); called by muse, mutect2
- SLC16A5 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 16/168 reads (10%) | called by muse, mutect2
- SLC35E2B | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SLC6A17 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- SMPD3 | c.1602C>A p.D534E | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNRNP200 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SNX25 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SORL1 | c.501C>G p.F167L | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SP2 | c.1545G>C p.K515N | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SPATA5L1 | c.1435-1G>C p.X479_splice | Splice Site (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- SRPX2 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.803); called by muse, mutect2
- SVEP1 | c.10525C>G p.L3509V | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SYTL1 | c.1075G>C p.G359R (on ENST00000543823; = p.G347R on NM_032872.3) | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TCF24 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.145); called by muse, mutect2
- TENM2 | c.8263G>C p.E2755Q (on ENST00000518659 / NM_001122679.2; = p.E2516Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 110/255 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TFE3 | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2
- TFIP11 | c.1209C>G p.I403M | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.476); called by muse, mutect2
- TMEM268 | c.285C>G p.I95M | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- TMEM38A | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- TMPRSS13 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- TNFSF11 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 83/163 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TNK2 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- TOP3A | c.1965C>G p.I655M | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- TRAV22 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRIM21 | c.1319G>A p.G440E | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.059); called by muse, mutect2
- TRIM4 | c.1263G>A p.W421* | Nonsense Mutation (SNP) | VAF 27/223 reads (12%) | called by muse, mutect2, varscan2
- TRPV4 | c.421C>G p.Q141E | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRRAP | c.11156G>C p.G3719A (on ENST00000359863 / NM_001244580.1; = p.G3690A on NM_003496.3) | Missense Mutation (SNP) | VAF 9/221 reads (4%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.714); called by muse, mutect2
- TSNARE1 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TTLL4 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- TTPAL | c.101C>A p.S34* | Nonsense Mutation (SNP) | VAF 11/165 reads (7%) | called by muse, mutect2
- TUBGCP4 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TUT4 | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.014); called by muse, mutect2
- TYK2 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- UBA2 | c.686C>G p.S229C | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- UBE2O | c.1904G>C p.G635A | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.854); called by muse, mutect2
- UBE4B | c.2932G>C p.E978Q (on ENST00000343090 / NM_001105562.3; = p.E849Q on NM_006048.5) | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UBLCP1 | c.775C>G p.L259V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.94); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- UBR1 | c.1002C>G p.I334M | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2
- ULK1 | c.3119G>A p.R1040K | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- USH1G | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 77/136 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); called by mutect2, varscan2
- USP11 | c.1303G>A p.D435N (on ENST00000218348; = p.D392N on NM_001371072.1) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- USP16 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, varscan2
- USP40 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- USPL1 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- VCAN | c.3466C>G p.P1156A | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VN1R1 | c.163C>G p.Q55E | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.851); called by muse, mutect2
- WDR26 | c.608C>T p.S203F (on ENST00000414423 / NM_001379403.1; = p.S103F on NM_025160.7) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- WNK2 | c.5700G>A p.M1900I (on ENST00000297954 / NM_001282394.1; = p.M1863I on NM_006648.3) | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.026); called by muse, varscan2
- XPO1 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- XPOT | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- YTHDC2 | c.3502G>A p.G1168S | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ZFP36 | c.923G>C p.G308A (on ENST00000594442; = p.G302A on NM_003407.5) | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- ZFYVE16 | c.1511C>G p.S504* | Nonsense Mutation (SNP) | VAF 69/161 reads (43%) | called by muse, mutect2, varscan2
- ZFYVE9 | c.4069G>C p.D1357H | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- ZNF227 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- ZNF350 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- ZNF445 | c.2259G>C p.Q753H | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF469 | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ZNF594 | c.1999_2011del p.L667Rfs*111 | Frame Shift Del (DEL) | VAF 35/121 reads (29%) | called by mutect2, pindel, varscan2
- ZNF609 | c.2181G>C p.K727N | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2
- ZNF709 | c.1138C>T p.Q380* | Nonsense Mutation (SNP) | VAF 11/272 reads (4%) | called by muse, mutect2
- ZNF768 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); called by muse, mutect2
- ZNRF4 | c.560A>G p.N187S | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ABCB9 | c.2127C>T p.L709= (on ENST00000280560 / NM_019625.4; = p.L666= on NM_019624.3) | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as rs770665149; called by muse, mutect2, varscan2
- ABCC8 | c.885C>T p.F295= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs778990778, COSV56852451; called by muse, mutect2, varscan2
- AC004922.1 | c.1626C>T p.F542= | Silent (SNP) | VAF 57/145 reads (39%) | catalogued as COSV53164933; called by mutect2, varscan2
- AHNAK | c.2925G>A p.L975= | Silent (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2, varscan2
- AKAP9 | c.7938G>A p.L2646= (on ENST00000359028; = p.L2622= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- ALG12 | c.834C>T p.F278= | Silent (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- AMOTL2 | c.1974C>A p.I658= | Silent (SNP) | VAF 15/89 reads (17%) | called by muse, mutect2, varscan2
- ANKRD17 | c.171C>T p.V57= | Silent (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- ANO7 | c.2424C>T p.L808= (on ENST00000274979; = p.L754= on NM_001370694.2) | Silent (SNP) | VAF 4/25 reads (16%) | called by mutect2, varscan2
- ASPH | c.2082G>A p.V694= | Silent (SNP) | VAF 46/100 reads (46%) | called by muse, varscan2
- ATP5ME | c.63C>T p.L21= | Silent (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- ATP8B4 | c.2523C>G p.V841= | Silent (SNP) | VAF 30/75 reads (40%) | called by muse, mutect2, varscan2
- AXIN1 | c.408G>A p.K136= | Silent (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- BEGAIN | c.1446C>T p.L482= | Silent (SNP) | VAF 51/100 reads (51%) | catalogued as rs372589914; called by muse, mutect2, varscan2
- BUB3 | c.237G>A p.L79= | Silent (SNP) | VAF 19/34 reads (56%) | called by muse, mutect2, varscan2
- BYSL | c.723G>A p.L241= | Silent (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- C2CD3 | c.2229C>A p.T743= | Silent (SNP) | VAF 6/145 reads (4%) | called by muse, mutect2
- C2CD4A | c.1109G>A p.*370= | Silent (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2
- C9orf78 | c.240G>A p.K80= | Silent (SNP) | VAF 73/237 reads (31%) | called by muse, mutect2, varscan2
- CACNA1D | c.4260C>T p.L1420= (on ENST00000350061 / NM_001128840.3; = p.L1440= on NM_000720.4) | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as COSV55466662, COSV99858326; called by muse, mutect2, varscan2
- CAMTA2 | c.153G>C p.L51= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV61833676; called by muse, varscan2
- CBR3 | c.165G>A p.L55= | Silent (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- CCDC185 | c.1422G>A p.L474= | Silent (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- CDH23 | c.5493C>T p.L1831= | Silent (SNP) | VAF 46/99 reads (46%) | catalogued as rs770012368, COSV99820154; called by muse, mutect2, varscan2
- CEP295NL | c.768C>T p.L256= | Silent (SNP) | VAF 39/350 reads (11%) | catalogued as rs761379613, COSV53162642; called by muse, mutect2, varscan2
- CFAP47 | c.4080G>A p.V1360= | Silent (SNP) | VAF 81/85 reads (95%) | called by muse, mutect2, varscan2
- CHKB | c.234C>T p.L78= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs929019284; called by muse, mutect2, varscan2
- CLEC16A | c.18G>A p.R6= | Silent (SNP) | VAF 7/77 reads (9%) | catalogued as COSV59329118; called by muse, mutect2
- CNTNAP5 | c.3669A>T p.T1223= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as COSV70491187; called by muse, mutect2, varscan2
- CPNE2 | c.391C>T p.L131= | Silent (SNP) | VAF 66/230 reads (29%) | catalogued as COSV99321249; called by muse, varscan2
- CPT1A | c.2262G>A p.L754= | Silent (SNP) | VAF 31/262 reads (12%) | catalogued as COSV55754984; called by muse, mutect2, varscan2
- DALRD3 | c.552G>A p.E184= (on ENST00000341949 / NM_001009996.3; = p.E17= on NM_018114.5) | Silent (SNP) | VAF 50/193 reads (26%) | catalogued as rs1393264539, COSV58246292; called by muse, mutect2, varscan2
- DCAF1 | c.4089C>T p.D1363= | Silent (SNP) | VAF 12/287 reads (4%) | catalogued as COSV60046856; called by muse, mutect2
- DCAF17 | c.120G>A p.V40= | Silent (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- DFFA | c.615C>A p.L205= | Silent (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- DGKG | c.1818C>T p.F606= | Silent (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- DGKQ | c.1857C>T p.F619= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as rs199695928; called by muse, mutect2, varscan2
- DHX37 | c.2685G>A p.L895= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- DNA2 | c.3081G>A p.E1027= | Silent (SNP) | VAF 123/254 reads (48%) | called by muse, mutect2, varscan2
- DNAH2 | c.11973G>C p.V3991= | Silent (SNP) | VAF 7/192 reads (4%) | called by muse, mutect2
- DNAJC13 | c.4839G>A p.L1613= | Silent (SNP) | VAF 61/195 reads (31%) | catalogued as rs757547954; called by muse, mutect2, varscan2
- EDA2R | c.498C>T p.F166= | Silent (SNP) | VAF 31/32 reads (97%) | called by muse, mutect2, varscan2
- EEF1A2 | c.72G>T p.T24= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV53205417; called by muse, mutect2, varscan2
- EFCAB1 | c.522G>A p.V174= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as rs72640529; called by muse, mutect2, varscan2
- EFCAB5 | c.417G>A p.L139= | Silent (SNP) | VAF 59/120 reads (49%) | catalogued as rs1442836095, COSV57926222; called by muse, mutect2, varscan2
- EHD4 | c.48C>T p.G16= | Silent (SNP) | VAF 13/21 reads (62%) | called by muse, mutect2, varscan2
- EIF3H | c.486C>G p.L162= | Silent (SNP) | VAF 43/110 reads (39%) | called by muse, mutect2, varscan2
- EXOC3 | c.1923C>T p.F641= | Silent (SNP) | VAF 11/18 reads (61%) | called by muse, mutect2, varscan2
- FAM155A | c.432G>A p.K144= | Silent (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- FAN1 | c.2553C>T p.F851= | Silent (SNP) | VAF 36/65 reads (55%) | called by muse, mutect2, varscan2
- FBXO44 | c.513G>T p.G171= | Silent (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
- FNIP2 | c.2445C>T p.H815= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as rs372078616; called by muse, mutect2, varscan2
- FOXC1 | c.486C>T p.F162= | Silent (SNP) | VAF 29/82 reads (35%) | called by muse, mutect2, varscan2
- GADD45B | c.482G>A p.*161= | Silent (SNP) | VAF 29/86 reads (34%) | called by muse, mutect2, varscan2
- GIMAP2 | c.255G>A p.K85= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as COSV56234968; called by muse, mutect2, varscan2
- GJA9 | c.765C>T p.F255= | Silent (SNP) | VAF 10/179 reads (6%) | called by muse, mutect2
- GM2A | c.417C>A p.P139= | Silent (SNP) | VAF 58/118 reads (49%) | called by muse, mutect2, varscan2
- GOLGA1 | c.2202C>T p.L734= | Silent (SNP) | VAF 66/187 reads (35%) | called by muse, mutect2, varscan2
- GPR179 | c.1683C>G p.L561= (on ENST00000621958; = p.L560= on NM_001004334.4) | Silent (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- GRK4 | c.1566C>T p.F522= | Silent (SNP) | VAF 66/143 reads (46%) | called by muse, mutect2, varscan2
- GRM8 | c.2043G>A p.K681= | Silent (SNP) | VAF 53/145 reads (37%) | catalogued as COSV58843449; called by muse, mutect2, varscan2
- H2BC7 | c.57G>A p.V19= | Silent (SNP) | VAF 13/226 reads (6%) | catalogued as rs1448607487, COSV61912438; called by muse, mutect2
- H2BC8 | c.213C>T p.F71= | Silent (SNP) | VAF 41/111 reads (37%) | catalogued as rs1561989160, COSV55126320, COSV55126971; called by muse, mutect2, varscan2
- HSPA4 | c.993G>A p.K331= | Silent (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- ID2 | c.258C>T p.V86= | Silent (SNP) | VAF 34/65 reads (52%) | catalogued as rs1430479811; called by muse, mutect2, varscan2
- IFT122 | c.999C>T p.S333= (on ENST00000348417 / NM_052989.3; = p.S274= on NM_018262.4) | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- IGHE | c.399C>T p.L133= | Silent (SNP) | VAF 7/107 reads (7%) | called by muse, mutect2
- INTS1 | c.1953C>T p.D651= | Silent (SNP) | VAF 29/96 reads (30%) | called by muse, mutect2, varscan2
- IRS2 | c.336G>A p.L112= | Silent (SNP) | VAF 33/77 reads (43%) | called by muse, varscan2
- ITPRIPL2 | c.738C>G p.L246= | Silent (SNP) | VAF 46/106 reads (43%) | called by muse, mutect2, varscan2
- KCNA10 | c.1146C>T p.L382= | Silent (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- KCNJ14 | c.30C>T p.L10= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs928639669, COSV53519720; called by mutect2, varscan2
- KEL | c.382C>A p.R128= | Silent (SNP) | VAF 62/206 reads (30%) | catalogued as CM012385; called by muse, mutect2, varscan2
- KIF13B | c.5151G>A p.V1717= | Silent (SNP) | VAF 95/100 reads (95%) | called by muse, mutect2, varscan2
- KIF20A | c.1755G>A p.E585= | Silent (SNP) | VAF 36/79 reads (46%) | called by muse, mutect2, varscan2
- KIF25 | c.312C>G p.L104= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100596262; called by muse, mutect2, varscan2
- KLHL30 | c.294C>T p.I98= | Silent (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- KLRK1 | c.273G>A p.L91= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as rs1462789189; called by muse, mutect2
- KRT5 | c.195C>T p.L65= | Silent (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- KRTAP16-1 | c.1533C>T p.A511= | Silent (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- LCNL1 | c.495G>A p.*165= | Silent (SNP) | VAF 33/80 reads (41%) | called by muse, mutect2, varscan2
- LCORL | c.57C>T p.A19= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as rs1331514400; called by muse, varscan2
- LOXHD1 | c.4737G>A p.E1579= | Silent (SNP) | VAF 58/132 reads (44%) | catalogued as rs1180193078; called by muse, mutect2, varscan2
- LPA | c.4707G>A p.V1569= | Silent (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- LRIF1 | c.420G>A p.V140= | Silent (SNP) | VAF 7/141 reads (5%) | catalogued as rs1201220133; called by muse, mutect2
- LRP2 | c.9741G>A p.Q3247= | Silent (SNP) | VAF 66/173 reads (38%) | called by muse, mutect2, varscan2
- MAGEB10 | c.576G>A p.L192= | Silent (SNP) | VAF 44/45 reads (98%) | called by muse, mutect2, varscan2
- MAP7 | c.957C>T p.P319= | Silent (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- MCM2 | c.1278C>T p.L426= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as rs147725704; called by muse, varscan2
- MED1 | c.2109G>A p.Q703= | Silent (SNP) | VAF 17/170 reads (10%) | called by muse, mutect2
- MED13L | c.1158C>T p.L386= | Silent (SNP) | VAF 42/85 reads (49%) | catalogued as rs371359246, COSV99927498; called by muse, varscan2
- MUC16 | c.37017G>A p.R12339= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as rs796358571, COSV104431812, COSV67479245; called by muse, mutect2, varscan2
- MUC16 | c.9039C>G p.L3013= | Silent (SNP) | VAF 60/194 reads (31%) | catalogued as rs1157195393, COSV67447573; called by muse, mutect2, varscan2
- MYCBP2 | c.4285C>T p.L1429= (on ENST00000357337; = p.L1467= on NM_015057.5) | Silent (SNP) | VAF 62/137 reads (45%) | called by muse, mutect2, varscan2
- MYT1L | c.3492G>A p.Q1164= | Silent (SNP) | VAF 85/181 reads (47%) | catalogued as COSV67702036; called by muse, mutect2, varscan2
- NCAN | c.1014C>T p.F338= | Silent (SNP) | VAF 62/167 reads (37%) | called by muse, mutect2, varscan2
- NCAPH2 | c.399C>G p.L133= | Silent (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- NR2F6 | c.630C>T p.L210= | Silent (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- NRXN3 | c.1395G>A p.R465= | Silent (SNP) | VAF 60/126 reads (48%) | catalogued as rs1475235614; called by muse, mutect2, varscan2
- NVL | c.51C>T p.V17= | Silent (SNP) | VAF 42/99 reads (42%) | called by muse, mutect2, varscan2
- OR4S1 | c.330C>A p.I110= | Silent (SNP) | VAF 66/127 reads (52%) | catalogued as rs1383455746; called by muse, mutect2, varscan2
- OR5L1 | c.780C>T p.C260= | Silent (SNP) | VAF 102/183 reads (56%) | catalogued as rs759953541, COSV99081999; called by muse, mutect2, varscan2
- OSCAR | c.271C>T p.L91= | Silent (SNP) | VAF 17/217 reads (8%) | called by muse, mutect2
- P2RY2 | c.339C>T p.F113= | Silent (SNP) | VAF 34/69 reads (49%) | called by muse, mutect2, varscan2
- P3H1 | c.372C>T p.L124= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as rs759316608; called by muse, mutect2, varscan2
- PADI3 | c.213C>T p.D71= | Silent (SNP) | VAF 7/128 reads (5%) | catalogued as rs550960710, COSV64935265; called by muse, mutect2
- PARP1 | c.783G>A p.L261= | Silent (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- PCDH7 | c.780G>A p.L260= | Silent (SNP) | VAF 7/125 reads (6%) | catalogued as COSV62338498; called by muse, mutect2
- PCDHA3 | c.756C>G p.L252= | Silent (SNP) | VAF 55/110 reads (50%) | called by muse, mutect2, varscan2
- PCDHB4 | c.1005G>A p.E335= | Silent (SNP) | VAF 6/136 reads (4%) | catalogued as rs782557064; called by muse, mutect2
- PCDHGA2 | c.2265C>T p.H755= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as rs752681745; called by muse, mutect2, varscan2
- PCDHGB6 | c.2157C>T p.L719= | Silent (SNP) | VAF 100/200 reads (50%) | called by muse, mutect2
- PHF8 | c.27G>A p.Q9= | Silent (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- PKHD1 | c.11802C>T p.V3934= | Silent (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- PLBD2 | c.819C>T p.V273= | Silent (SNP) | VAF 15/164 reads (9%) | called by muse, mutect2
- PLK3 | c.219C>T p.F73= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs759735743, COSV64728444; called by muse, mutect2, varscan2
- PLK3 | c.576C>T p.F192= | Silent (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- PNMT | c.717G>A p.V239= | Silent (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- PODNL1 | c.270C>T p.L90= | Silent (SNP) | VAF 43/106 reads (41%) | called by muse, mutect2, varscan2
- POU1F1 | c.321C>T p.F107= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV60155514, COSV60157295; called by muse, mutect2, varscan2
- PRF1 | c.1650G>C p.R550= | Silent (SNP) | VAF 10/214 reads (5%) | catalogued as rs1483832689; called by muse, mutect2
- PRKCG | c.1824C>T p.I608= | Silent (SNP) | VAF 10/194 reads (5%) | catalogued as rs1213650646; called by muse, mutect2
- PSMD2 | c.687C>T p.V229= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as rs756877559, COSV59529443; called by muse, mutect2, varscan2
- RABGAP1 | c.204G>C p.L68= | Silent (SNP) | VAF 9/258 reads (3%) | called by muse, mutect2
- RARA | c.105C>T p.L35= | Silent (SNP) | VAF 63/122 reads (52%) | catalogued as COSV54192343; called by muse, mutect2, varscan2
- RBFA | c.279G>C p.L93= | Silent (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2, varscan2
- RBM15B | c.387C>T p.P129= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs1553621567; called by muse, mutect2
- RCN2 | c.30G>A p.L10= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1399571095; called by muse, mutect2, varscan2
- RIMBP2 | c.756C>T p.I252= | Silent (SNP) | VAF 71/164 reads (43%) | catalogued as rs1336768863; called by muse, mutect2, varscan2
- RNF216 | c.2500C>T p.L834= (on ENST00000425013 / NM_207116.3; = p.L891= on NM_207111.4) | Silent (SNP) | VAF 9/216 reads (4%) | catalogued as COSV101111373, COSV66290875; called by muse, mutect2
- RTL9 | c.1884C>T p.F628= | Silent (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- SALL3 | c.1608C>T p.G536= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs1332201156; called by muse, mutect2, varscan2
- SCART1 | c.1962C>T p.F654= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs745554266, COSV62986254; called by muse, mutect2, varscan2
- SCIN | c.1473C>T p.L491= (on ENST00000297029 / NM_001112706.3; = p.L244= on NM_033128.3) | Silent (SNP) | VAF 49/132 reads (37%) | called by muse, mutect2, varscan2
- SCRIB | c.903G>A p.L301= | Silent (SNP) | VAF 43/87 reads (49%) | called by muse, varscan2
- SCRIB | c.825G>A p.Q275= | Silent (SNP) | VAF 74/140 reads (53%) | called by muse, varscan2
- SEMA3E | c.432C>T p.F144= | Silent (SNP) | VAF 11/260 reads (4%) | called by muse, mutect2
- SENP2 | c.15G>A p.L5= | Silent (SNP) | VAF 74/295 reads (25%) | catalogued as rs571487235; called by muse, mutect2, varscan2
- SENP6 | c.2901C>T p.I967= | Silent (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- SH3PXD2B | c.1074C>T p.L358= | Silent (SNP) | VAF 12/188 reads (6%) | catalogued as COSV61128931; called by muse, mutect2
- SIM2 | c.207C>T p.R69= | Silent (SNP) | VAF 56/177 reads (32%) | catalogued as COSV51773553; called by muse, varscan2
- SLC12A6 | c.3264G>A p.V1088= (on ENST00000354181 / NM_001365088.1; = p.V1037= on NM_005135.2) | Silent (SNP) | VAF 44/86 reads (51%) | called by muse, mutect2, varscan2
- SLC15A3 | c.735C>G p.L245= | Silent (SNP) | VAF 5/84 reads (6%) | catalogued as COSV57171447; called by muse, mutect2
- SLC35B4 | c.780C>T p.L260= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as rs553898015; called by muse, mutect2
- SLC43A1 | c.72C>G p.L24= | Silent (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2
- SLC5A9 | c.1611C>T p.L537= | Silent (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- SMARCD2 | c.606C>T p.F202= | Silent (SNP) | VAF 55/118 reads (47%) | called by muse, mutect2, varscan2
- SMG6 | c.1911G>A p.Q637= | Silent (SNP) | VAF 44/82 reads (54%) | catalogued as COSV53963963; called by muse, mutect2, varscan2
- SNX25 | c.657G>A p.L219= | Silent (SNP) | VAF 29/79 reads (37%) | called by muse, mutect2, varscan2
- SPDYC | c.48C>T p.I16= | Silent (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- SPECC1 | c.2998C>T p.L1000= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- SPINT1 | c.543G>A p.L181= | Silent (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- SYNRG | c.1710C>T p.F570= | Silent (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- SYT12 | c.699G>A p.K233= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as rs961580375; called by muse, mutect2, varscan2
- TBC1D9B | c.2373G>A p.L791= | Silent (SNP) | VAF 31/62 reads (50%) | called by muse, mutect2, varscan2
- TBC1D9B | c.2118C>T p.V706= | Silent (SNP) | VAF 8/186 reads (4%) | called by muse, mutect2
- TGM4 | c.1374C>A p.L458= | Silent (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- TMEM132C | c.2340G>A p.Q780= | Silent (SNP) | VAF 36/99 reads (36%) | called by muse, mutect2, varscan2
- TPTE | c.508C>T p.L170= (on ENST00000618007 / NM_199261.4; = p.L152= on NM_199259.4) | Silent (SNP) | VAF 16/163 reads (10%) | called by muse, mutect2
- TRAF5 | c.1284C>T p.I428= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs1473186093, COSV99807189; called by muse, mutect2, varscan2
- TRAPPC11 | c.684C>T p.F228= | Silent (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- TRIM14 | c.654C>T p.A218= | Silent (SNP) | VAF 16/188 reads (9%) | catalogued as rs779274244; called by muse, mutect2
- TSGA10IP | c.687G>C p.L229= | Silent (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.2475C>T p.I825= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- TUBE1 | c.711G>A p.K237= | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- UBA3 | c.582C>T p.S194= | Silent (SNP) | VAF 68/235 reads (29%) | catalogued as COSV62739867; called by muse, mutect2, varscan2
- UBE2R2 | c.447G>A p.R149= | Silent (SNP) | VAF 52/174 reads (30%) | catalogued as rs771029242; called by muse, mutect2, varscan2
- UHRF2 | c.1887G>A p.R629= | Silent (SNP) | VAF 5/100 reads (5%) | catalogued as rs1448746667; called by muse, mutect2
- UMODL1 | c.3411C>T p.V1137= (on ENST00000408910 / NM_001004416.2; = p.V1265= on NM_173568.3) | Silent (SNP) | VAF 62/246 reads (25%) | called by muse, mutect2, varscan2
- UNC80 | c.8754G>A p.K2918= | Silent (SNP) | VAF 45/86 reads (52%) | called by muse, mutect2, varscan2
- UPF2 | c.105G>A p.E35= | Silent (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- USP51 | c.1575C>T p.F525= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs372008917; called by muse, mutect2, varscan2
- UST | c.1005G>A p.Q335= | Silent (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- VCPIP1 | c.766C>T p.L256= | Silent (SNP) | VAF 41/83 reads (49%) | catalogued as rs1229829503; called by muse, mutect2, varscan2
- VILL | c.876G>A p.K292= | Silent (SNP) | VAF 56/198 reads (28%) | called by muse, mutect2, varscan2
- VPS13C | c.5610C>T p.L1870= (on ENST00000644861 / NM_020821.3; = p.L1827= on NM_017684.5) | Silent (SNP) | VAF 35/60 reads (58%) | called by muse, mutect2, varscan2
- VWF | c.1881C>T p.A627= | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- WDR4 | c.948C>G p.L316= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs1276029054; called by muse, mutect2, varscan2
- WDR49 | c.780G>A p.V260= (on ENST00000308378 / NM_001366158.1; = p.V601= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- WDR49 | c.663C>T p.F221= (on ENST00000308378 / NM_001366158.1; = p.F562= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 62/183 reads (34%) | called by muse, mutect2, varscan2
- ZC3H6 | c.1963C>T p.L655= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as rs1321508463; called by muse, mutect2
- ZC3HAV1 | c.2301C>A p.L767= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV54299885, COSV99649060; called by muse, varscan2
- ZNF329 | c.534G>A p.K178= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV63771747; called by muse, mutect2
- ZNF528 | c.1260G>A p.Q420= | Silent (SNP) | VAF 8/192 reads (4%) | called by muse, mutect2
- ZNF558 | c.483C>T p.F161= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as rs782520536; called by muse, mutect2, varscan2
- ZNF654 | c.2728C>T p.L910= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs763673082; called by muse, mutect2, varscan2
- ZNF697 | c.483C>T p.R161= | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as COSV101360331; called by muse, mutect2, varscan2
- A2M | chr12:9067676 G>C | 3'Flank (SNP) | VAF 7/86 reads (8%) | catalogued as rs1329531086; called by muse, mutect2
- ABCB8 | c.147-53C>A | Intron (SNP) | VAF 29/84 reads (35%) | called by muse, mutect2, varscan2
- ABCC6P2 | n.222C>G | RNA (SNP) | VAF 26/168 reads (15%) | called by muse, mutect2, varscan2
- ABCF1 | c.*450C>T | 3'UTR (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- ABHD2 | c.*1960C>T | 3'UTR (SNP) | VAF 9/155 reads (6%) | called by muse, mutect2
- ABI2 | c.*4325G>C | 3'UTR (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2
- ABL2 | c.*7641G>A | 3'UTR (SNP) | VAF 29/82 reads (35%) | called by muse, mutect2, varscan2
- ABL2 | c.*1165G>A | 3'UTR (SNP) | VAF 31/59 reads (53%) | called by muse, varscan2
- AC002511.3 | chr19:35407740 G>A | 5'Flank (SNP) | VAF 31/85 reads (36%) | catalogued as rs1352542915; called by muse, mutect2, varscan2
- AC007557.3 | n.2730G>A | RNA (SNP) | VAF 13/191 reads (7%) | called by muse, mutect2
- AC009779.3 | c.*1110G>T | 3'UTR (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2
- AC025279.2 | n.525G>T | RNA (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- AC026410.1 | n.767C>T | RNA (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- AC068643.2 | n.584T>C | RNA (SNP) | VAF 10/240 reads (4%) | called by muse, mutect2
- AC243965.1 | n.582C>T | RNA (SNP) | VAF 28/47 reads (60%) | catalogued as rs1337920762; called by muse, mutect2, varscan2
- ACADM | c.*169C>G | 3'UTR (SNP) | VAF 5/92 reads (5%) | catalogued as COSV63719660; called by muse, mutect2
- ACER2 | c.*459C>T | 3'UTR (SNP) | VAF 53/190 reads (28%) | called by muse, mutect2, varscan2
- ACTR2 | c.*2361C>G | 3'UTR (SNP) | VAF 15/24 reads (63%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.474+123G>A | Intron (SNP) | VAF 28/129 reads (22%) | called by muse, mutect2
- ADAR | c.*854C>G | 3'UTR (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2
- ADCK2 | chr7:140695639 C>T | 3'Flank (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- ADCYAP1 | c.-90C>T | 5'UTR (SNP) | VAF 20/97 reads (21%) | called by muse, mutect2, varscan2
- ADGRL2 | c.-248+57059C>T | Intron (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- AGPAT3 | c.*241G>C | 3'UTR (SNP) | VAF 90/400 reads (23%) | called by muse, varscan2
- AHCYL1 | c.*656G>A | 3'UTR (SNP) | VAF 31/64 reads (48%) | called by muse, mutect2, varscan2
- AKAP1 | c.*731G>C | 3'UTR (SNP) | VAF 7/73 reads (10%) | called by mutect2, varscan2
- AKAP13 | c.478+2881C>G | Intron (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- AKAP9 | chr7:91940932 C>T | 5'Flank (SNP) | VAF 37/116 reads (32%) | called by muse, mutect2, varscan2
- AKR1B10 | c.742-32G>C | Intron (SNP) | VAF 6/152 reads (4%) | called by muse, mutect2
- AL353804.7 | chrX:73847012 G>C | 5'Flank (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- AL592490.1 | c.*330C>G | 3'UTR (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- AL645929.2 | chr6:29888472 C>T | 5'Flank (SNP) | VAF 20/61 reads (33%) | catalogued as rs780496766; called by muse, mutect2, varscan2
- ALDH1A3 | c.99+692G>A | Intron (SNP) | VAF 56/102 reads (55%) | called by muse, mutect2, varscan2
- ALPK3 | c.*4297C>T | 3'UTR (SNP) | VAF 25/51 reads (49%) | catalogued as rs1425900610; called by muse, mutect2, varscan2
- ALS2 | c.*1374C>T | 3'UTR (SNP) | VAF 6/8 reads (75%) | called by muse, mutect2, varscan2
- AMDHD2 | c.*627G>A | 3'UTR (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- ANKRD13B | c.1652+89C>T | Intron (SNP) | VAF 22/35 reads (63%) | catalogued as rs887778637; called by muse, mutect2, varscan2
- ANKRD17 | c.*2558G>A | 3'UTR (SNP) | VAF 19/148 reads (13%) | called by muse, mutect2, varscan2
- ANKRD18B | c.2992-763C>T | Intron (SNP) | VAF 17/294 reads (6%) | called by muse, mutect2
- ANKRD28 | c.*1335G>A | 3'UTR (SNP) | VAF 34/128 reads (27%) | called by muse, mutect2, varscan2
- ANKRD28 | c.1962-24G>A | Intron (SNP) | VAF 94/285 reads (33%) | catalogued as rs1270578776; called by muse, mutect2, varscan2
- ANO6 | c.*2832G>A | 3'UTR (SNP) | VAF 45/86 reads (52%) | called by muse, mutect2, varscan2
- AP1G2 | c.-60G>A | 5'UTR (SNP) | VAF 20/34 reads (59%) | catalogued as rs979322732, COSV58113041; called by muse, mutect2, varscan2
- APBB2 | c.*2690G>C | 3'UTR (SNP) | VAF 45/84 reads (54%) | called by muse, mutect2, varscan2
- APBB2 | c.1527-11797G>A | Intron (SNP) | VAF 23/84 reads (27%) | called by muse, mutect2, varscan2
- APLP1 | c.292-92G>A | Intron (SNP) | VAF 13/40 reads (33%) | catalogued as rs988910159; called by muse, mutect2, varscan2
- APMAP | chr20:24992873 G>A | 5'Flank (SNP) | VAF 9/112 reads (8%) | called by muse, mutect2
- APOE | c.-23-208G>A | Intron (SNP) | VAF 36/131 reads (27%) | called by muse, varscan2
- AR | c.*2107C>T | 3'UTR (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- ARFGEF1 | c.*845G>A | 3'UTR (SNP) | VAF 29/57 reads (51%) | catalogued as rs1175502274; called by muse, mutect2, varscan2
- ARHGAP10 | c.*494C>G | 3'UTR (SNP) | VAF 27/57 reads (47%) | called by muse, mutect2, varscan2
- ARHGAP11A | c.1106-83G>T | Intron (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- ARHGAP24 | c.*167G>C | 3'UTR (SNP) | VAF 37/71 reads (52%) | called by muse, mutect2, varscan2
- ARL5C | c.107+57G>T | Intron (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- ARL5C | c.107+56G>T | Intron (SNP) | VAF 5/100 reads (5%) | called by muse, mutect2
- ARNT2 | c.*3562T>G | 3'UTR (SNP) | VAF 12/324 reads (4%) | called by muse, mutect2
- ASPHD2 | c.*1510G>T | 3'UTR (SNP) | VAF 21/43 reads (49%) | catalogued as rs1005905452; called by muse, mutect2, varscan2
- ATP1A3 | c.3052+32del | Intron (DEL) | VAF 22/78 reads (28%) | called by mutect2, varscan2
- ATP6V0A1 | c.2421-485C>G | Intron (SNP) | VAF 70/164 reads (43%) | called by muse, mutect2, varscan2
- ATP6V0E2 | chr7:149873910 G>A | 5'Flank (SNP) | VAF 25/94 reads (27%) | called by muse, mutect2, varscan2
- ATP6V1C1 | c.*2325G>A | 3'UTR (SNP) | VAF 32/63 reads (51%) | called by muse, mutect2, varscan2
- ATP6V1C1 | c.*2689G>A | 3'UTR (SNP) | VAF 18/41 reads (44%) | called by mutect2, varscan2
- B3GLCT | c.*570G>A | 3'UTR (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- B3GLCT | c.*992G>C | 3'UTR (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- BAALC | chr8:103228450 G>A | 3'Flank (SNP) | VAF 39/74 reads (53%) | called by muse, mutect2, varscan2
- BAIAP3 | c.*573C>G | 3'UTR (SNP) | VAF 42/90 reads (47%) | called by muse, mutect2, varscan2
- BAP1 | c.932-48C>G | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as rs1015084019; called by muse, mutect2, varscan2
- BDH1 | c.83+98C>G | Intron (SNP) | VAF 4/8 reads (50%) | called by muse, mutect2, varscan2
- BDKRB2 | c.74+1310G>C | Intron (SNP) | VAF 70/143 reads (49%) | called by muse, mutect2, varscan2
- BICRAL | c.*906G>C | 3'UTR (SNP) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- BIN1 | c.-131C>T | 5'UTR (SNP) | VAF 21/30 reads (70%) | called by muse, mutect2, varscan2
- BIRC3 | c.-292C>T | 5'UTR (SNP) | VAF 25/47 reads (53%) | called by muse, mutect2, varscan2
- BIRC8 | n.1008G>C | RNA (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- BMP1 | chr8:22165303 G>A | 5'Flank (SNP) | VAF 19/19 reads (100%) | called by muse, mutect2, varscan2
- BPNT2 | c.*1112C>T | 3'UTR (SNP) | VAF 23/80 reads (29%) | catalogued as rs995462662; called by muse, mutect2, varscan2
- BTG3 | c.311+621C>G | Intron (SNP) | VAF 13/21 reads (62%) | called by muse, mutect2, varscan2
- BTK | c.392-21C>G | Intron (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- BTN3A1 | c.1019-198C>G | Intron (SNP) | VAF 77/177 reads (44%) | called by muse, mutect2, varscan2
- C11orf96 | chr11:43943307 G>A | 3'Flank (SNP) | VAF 26/42 reads (62%) | called by muse, mutect2, varscan2
- C12orf66 | c.*272C>T | 3'UTR (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- C12orf76 | n.665-1823G>A | Intron (SNP) | VAF 10/16 reads (63%) | catalogued as rs1300613401; called by muse, mutect2, varscan2
- C14orf132 | chr14:96090035 C>G | 3'Flank (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- C14orf93 | c.-301G>A | 5'UTR (SNP) | VAF 13/125 reads (10%) | catalogued as rs1305656057; called by muse, mutect2, varscan2
- C1QL2 | c.*47C>T | 3'UTR (SNP) | VAF 14/38 reads (37%) | catalogued as rs1054354319; called by muse, mutect2, varscan2
- C1orf115 | c.*581C>G | 3'UTR (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2, varscan2
- C20orf197 | n.379C>T | RNA (SNP) | VAF 58/116 reads (50%) | called by muse, mutect2, varscan2
- C20orf197 | n.2551C>T | RNA (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- C21orf58 | c.-799G>A | 5'UTR (SNP) | VAF 36/173 reads (21%) | called by muse, mutect2, varscan2
- C22orf23 | c.-59G>A | 5'UTR (SNP) | VAF 20/105 reads (19%) | called by muse, mutect2, varscan2
- C2orf49 | c.*1315G>C | 3'UTR (SNP) | VAF 65/117 reads (56%) | called by muse, mutect2, varscan2
- C2orf81 | chr2:74421551 C>T | 5'Flank (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- C4orf33 | c.*1190G>A | 3'UTR (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- C5orf24 | c.*1627C>G | 3'UTR (SNP) | VAF 15/33 reads (45%) | catalogued as rs574283539; called by muse, mutect2, varscan2
- C7orf65 | n.1371C>T | RNA (SNP) | VAF 140/403 reads (35%) | catalogued as rs575239760; called by muse, mutect2, varscan2
- C8orf34 | c.1105+1759C>T | Intron (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- C9orf152 | c.-466G>A | 5'UTR (SNP) | VAF 32/113 reads (28%) | called by muse, mutect2, varscan2
- CA2 | c.233-261C>T | Intron (SNP) | VAF 16/35 reads (46%) | catalogued as rs1316584036; called by muse, mutect2, varscan2
- CA4 | c.-23A>T | 5'UTR (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- CAAP1 | c.*969C>T | 3'UTR (SNP) | VAF 25/75 reads (33%) | called by muse, mutect2, varscan2
- CACNA1E | c.*8154C>T | 3'UTR (SNP) | VAF 20/56 reads (36%) | called by muse, mutect2, varscan2
- CAMTA1 | c.46-13136C>T | Intron (SNP) | VAF 66/133 reads (50%) | catalogued as rs1435408048; called by muse, mutect2, varscan2
- CARD8 | c.351-712C>G | Intron (SNP) | VAF 6/23 reads (26%) | catalogued as COSV62873255; called by muse, mutect2
- CASP4 | c.-34C>A | 5'UTR (SNP) | VAF 116/242 reads (48%) | called by muse, mutect2, varscan2
- CASS4 | chr20:56458942 G>C | 3'Flank (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- CBX5 | c.*585C>T | 3'UTR (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- CCDC186 | c.*3015C>G | 3'UTR (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- CCDC69 | c.*282G>A | 3'UTR (SNP) | VAF 133/258 reads (52%) | called by muse, mutect2, varscan2
- CCDC71L | c.*92G>A | 3'UTR (SNP) | VAF 90/258 reads (35%) | called by muse, mutect2, varscan2
- CCDC8 | c.*271C>A | 3'UTR (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
637 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 637 other) are not listed here.
